Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8249, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8249-01A (Primary Tumor).

[REDACTED]

Stomach, total gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(-)/Muc6(-)/CD10(+ +)/cERB2(-),I type)

1. Location : middle third, Center at mid-body, lesser curvature
2. Gross type : Borrmann type 2
3. Histologic type : Adenocarcinoma, tubular moderately differentiated
4. Histologic type by Lauren : intestinal
5. Growth pattern: mixed expanding and infiltrative growth pattern
6. Size : 7.4x6.5cm
7. Depth of invasion : Tumor invades subserosa (pT3)
8. Resection margin : free from carcinoma
safety margins: distal 8.2cm, proximal 1.9cm
9. Lymph node metastasis : metastasis to 5 out of 99 regional lymph nodes (pN2)
(lesser curvature 5/47, greater curvature 0/52, #11 LN 0/0, #12 LN 0/0)
10. Lymphatic invasion : present, mild
11. Venous invasion : present, moderate
12. Perineural invasion : present, mild
13. Additional findings :
- Spleen, no tumor.
- Accessory spleen is identified, 0.5x0.4cm in size.
- Pit dysplasia in adjacent mucosa.

Specimen labeled as "anvil ring", biopsy:

No tumor.

Small intestine, jejunum, biopsy:

No tumor.

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

Source: NCI Genomic Data Commons file 511540f1-0066-493d-8667-2bf074b49028 (TCGA-HU-8249.508931EE-5E93-4E0B-BB41-0E6F85DF5570.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).